Somatic mutation profile of tumor specimen TCGA-CV-7248-01A (aliquot TCGA-CV-7248-01A-11D-2012-08) from TCGA case TCGA-CV-7248, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.2 years (23,082 days).
Specimen TCGA-CV-7248-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40d6fda4-2687-4d5d-9e24-0e75bb992363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7248-10A (Blood Derived Normal), aliquot TCGA-CV-7248-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed86575b-c1c4-4023-afc9-348a02d656a9

The open-access MAF lists 307 somatic variants for this specimen: 231 protein-altering or splice-affecting, 67 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 198, Silent 67, Nonsense Mutation 17, RNA 8, Splice Site 5, Frame Shift Del 5, Frame Shift Ins 4, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1904T>A p.L635H (on ENST00000272895 / NM_173076.3; = p.L317H on NM_015657.3) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as COSV99789561; called by muse, mutect2
- ABCB1 | c.3592C>G p.L1198V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV99712794; called by muse, mutect2, varscan2
- ABCB7 | c.1852G>A p.A618T (on ENST00000373394 / NM_001271696.3; = p.A619T on NM_004299.6) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99504243; called by muse, mutect2, varscan2
- ABCC9 | c.3508C>T p.P1170S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53982343, COSV99685423; called by muse, mutect2, varscan2
- ACTRT1 | c.241G>T p.G81* | Nonsense Mutation (SNP) | VAF 59/309 reads (19%) | catalogued as COSV64420117; called by muse, mutect2, varscan2
- ADAMTS19 | c.3385G>T p.G1129* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99177296; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1620G>A p.W540* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | catalogued as rs960091241, COSV99647130; called by muse, mutect2, varscan2
- ADGRB3 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV101000368; called by muse, mutect2, varscan2
- ADGRB3 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1304575172, COSV101000369; called by muse, mutect2, varscan2
- ADGRG4 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV99795240; called by muse, mutect2, varscan2
- ADGRL4 | c.163A>T p.I55F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV100875869; called by muse, mutect2
- AGTR2 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1440815286, COSV100903558, COSV100903598; called by muse, mutect2, varscan2
- AHNAK | c.4024G>T p.D1342Y | Missense Mutation (SNP) | VAF 57/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99947000; called by muse, mutect2, varscan2
- AKAP4 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100654239; called by muse, mutect2, varscan2
- AKAP9 | c.4963G>T p.V1655L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs769175497, COSV100662307; called by muse, mutect2, varscan2
- ALDH1L2 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99310956; called by muse, mutect2, varscan2
- AMPH | c.1158+1del p.X386_splice | Splice Site (DEL) | VAF 16/75 reads (21%) | catalogued as COSV57762532; called by mutect2, pindel, varscan2
- AMPH | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100341767; called by muse, mutect2, varscan2
- ANK2 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100001077; called by muse, mutect2, varscan2
- APC | c.4555del p.D1519Mfs*4 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as CD106467, COSV57339396, COSV57348482, COSV57356569; called by mutect2, pindel, varscan2
- ARHGAP45 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1293008391, COSV100490627; called by muse, mutect2
- ATAD2 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99784536; called by muse, mutect2, varscan2
- ATP11C | c.2531C>A p.A844E | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557747; called by muse, mutect2, varscan2
- ATRX | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV100969503, COSV64869199; called by muse, mutect2, varscan2
- ATXN7 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV99894254; called by muse, mutect2, varscan2
- BRCA1 | c.1990A>G p.R664G | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV100523928; called by muse, mutect2, varscan2
- CACNA1F | c.5006C>A p.P1669H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.647); catalogued as COSV100544681; called by muse, mutect2, varscan2
- CARD19 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100968658; called by muse, mutect2, varscan2
- CCPG1 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100197112; called by muse, mutect2
- CDCA7L | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100178838, COSV60976129; called by muse, mutect2, varscan2
- CDH10 | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52575032, COSV52578898; called by muse, mutect2, varscan2
- CELSR1 | c.5875G>T p.G1959W | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99417961; called by muse, mutect2, varscan2
- CFAP47 | c.2185T>C p.S729P | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as COSV99934864; called by muse, mutect2
- CKAP2 | c.1096G>T p.E366* (on ENST00000378037 / NM_001098525.2; = p.E365* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99318232; called by muse, mutect2, varscan2
- CLEC4F | c.1255G>T p.A419S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV99713691; called by muse, mutect2, varscan2
- CNOT1 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV100409104; called by muse, mutect2, varscan2
- CNTN6 | c.2363C>A p.S788Y | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs764051637, COSV100610501, COSV63192141; called by muse, mutect2, varscan2
- COL22A1 | c.4862G>T p.G1621V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV100277908; called by muse, mutect2, varscan2
- COL5A1 | c.702_703insTACT p.D235Yfs*2 | Frame Shift Ins (INS) | VAF 37/103 reads (36%) | catalogued as CI129051; called by mutect2, varscan2*
- COL6A3 | c.9280A>G p.T3094A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99797697; called by muse, mutect2, varscan2
- CSMD3 | c.6157C>A p.P2053T (on ENST00000297405 / NM_001363185.1; = p.P1949T on NM_052900.3) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV52219210, COSV99831986; called by muse, mutect2, varscan2
- CSNK2A1 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99424358; called by muse, mutect2, varscan2
- CYP26A1 | c.581T>A p.L194Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99814672; called by muse, mutect2, varscan2
- DHX34 | c.1351G>T p.G451W | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169483, COSV60895790; called by muse, mutect2, varscan2
- DIP2A | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV100595662; called by muse, mutect2, varscan2
- DNAH7 | c.2341A>G p.R781G | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100414864, COSV100418067; called by muse, mutect2, varscan2
- DNM1 | c.1491C>T p.A497= | Splice Region (SNP) | VAF 148/359 reads (41%) | catalogued as rs1044394311, COSV100359822; called by muse, mutect2, varscan2
- DOK6 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101234442; called by mutect2, varscan2
- DPPA2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as COSV72117935; called by muse, varscan2
- DRP2 | c.2197A>T p.S733C | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.319); catalogued as COSV100871879; called by muse, mutect2, varscan2
- E2F2 | c.288G>C p.R96S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV100674767; called by muse, mutect2, varscan2
- ECT2 | c.931C>T p.L311F (on ENST00000392692 / NM_001349098.2; = p.L280F on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV99221240; called by muse, mutect2, varscan2
- EHD3 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100434680; called by muse, mutect2, varscan2
- ENPP1 | c.2417G>C p.R806P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.746); catalogued as COSV100719497; called by muse, mutect2, varscan2
- EPAS1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99763120; called by muse, mutect2, varscan2
- EYS | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV100676285; called by muse, mutect2
- EYS | c.1297A>G p.K433E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100676286; called by muse, mutect2, varscan2
- FAM47B | c.1857C>G p.D619E | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.301); catalogued as COSV100264266; called by muse, mutect2, varscan2
- FAM47C | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV100792461, COSV63727614, COSV63729697; called by muse, mutect2, varscan2
- FAM83H | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV101186961; called by muse, mutect2, varscan2
- FANCM | c.2762G>T p.C921F | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV57504891, COSV99950934; called by muse, mutect2, varscan2
- FBLN2 | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as rs1343750129, COSV55491653; called by muse, mutect2, varscan2
- FBXO40 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100100567, COSV100100582, COSV57529254; called by muse, mutect2, varscan2
- FITM2 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101201992; called by muse, varscan2
- FLT1 | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV99151633; called by muse, mutect2, varscan2
- FOXJ2 | c.193G>T p.G65C | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99368413; called by muse, mutect2, varscan2
- FRK | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748817352, COSV73383814; called by muse, mutect2
- GAB3 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782464185, COSV65819814; called by muse, mutect2, varscan2
- GABRA2 | c.346T>A p.L116I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV100734142; called by muse, mutect2, varscan2
- GABRB1 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99781149; called by muse, mutect2, varscan2
- GNL3L | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100328299, COSV60575641; called by muse, mutect2, varscan2
- GP6 | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs779552982, COSV100117476; called by muse, mutect2
- GPRASP2 | c.340G>C p.A114P | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100176677; called by muse, mutect2, varscan2
- GRID1 | c.1426A>C p.K476Q | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV100023487; called by muse, mutect2, varscan2
- GRIN2C | c.1160G>C p.W387S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99500885; called by muse, mutect2, varscan2
- GRIN3A | c.1213A>G p.M405V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100701464; called by muse, mutect2, varscan2
- GRM3 | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100862483; called by muse, mutect2, varscan2
- GRM8 | c.2377A>G p.I793V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as rs767199883, COSV100282277; called by muse, mutect2, varscan2
- H2BC5 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.69); catalogued as rs754576866, COSV99175247; called by muse, mutect2, varscan2
- HCFC1 | c.4831G>T p.E1611* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV100128842; called by muse, mutect2, varscan2
- HDAC6 | c.2525G>T p.R842I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100490751; called by muse, mutect2
- HEPH | c.3422G>T p.R1141L (on ENST00000343002; = p.R874L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV100294680, COSV57959332; called by muse, mutect2, varscan2
- IGSF10 | c.4093A>T p.S1365C | Missense Mutation (SNP) | VAF 56/381 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV99178912; called by muse, mutect2, varscan2
- IL13RA1 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.73); catalogued as COSV100861714; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1508T>A p.L503Q (on ENST00000485419 / NM_001197113.1; = p.L427Q on NM_014575.3) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100540544; called by muse, mutect2, varscan2
- IRS4 | c.1013C>A p.A338D | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as COSV100929519; called by muse, mutect2, varscan2
- ITGB1BP2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99338746; called by muse, mutect2, varscan2
- ITGBL1 | c.717C>A p.C239* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101095286; called by mutect2, varscan2
- KCNH7 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100035429; called by muse, mutect2, varscan2
- KEAP1 | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99407680; called by muse, mutect2, varscan2
- KHDRBS2 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832964; called by muse, mutect2
- KIR2DL1 | c.924C>G p.C308W | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs2916014, COSV52412738; called by muse, mutect2
- KMT2D | c.13957A>T p.K4653* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99980443; called by muse, mutect2, varscan2
- LAMA2 | c.6145A>G p.K2049E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.42); catalogued as rs774208594, COSV101370367; called by muse, mutect2, varscan2
- LCOR | c.3047C>T p.S1016L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs759673171, COSV53714802, COSV53718328; called by muse, mutect2, varscan2
- LDHC | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99772444; called by muse, mutect2, varscan2
- LDHC | c.386C>A p.P129H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99772445; called by muse, mutect2, varscan2
- LHX3 | c.655G>T p.A219S (on ENST00000371748 / NM_178138.6; = p.A224S on NM_014564.5) | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs544993271, COSV100871187, COSV65581348; called by muse, mutect2, varscan2
- LHX9 | c.937-1G>C p.X313_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100435815; called by muse, mutect2, varscan2
- LIMA1 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV100372385; called by muse, mutect2, varscan2
- LRCH1 | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752401148, COSV100243582; called by muse, mutect2, varscan2
- LRRIQ3 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100598685, COSV63040969; called by muse, mutect2
- LY96 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV53026404, COSV99514381; called by muse, mutect2, varscan2
- MAGEA11 | c.1232C>A p.P411H | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV100290467; called by muse, varscan2
- MAGEE1 | c.2450G>T p.R817L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100819373, COSV63910064; called by muse, mutect2, varscan2
- MAGIX | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100891870, COSV66255649; called by muse, mutect2, varscan2
- MAP2 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV52306321; called by muse, mutect2, varscan2
- MCTP1 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV100386938; called by muse, mutect2
- MED12 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100377536, COSV61342522; called by mutect2, varscan2
- MEGF8 | c.4421G>A p.G1474D (on ENST00000251268 / NM_001271938.2; = p.G1407D on NM_001410.3) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1385102968, COSV99235814; called by muse, mutect2, varscan2
- MGAM | c.4497G>T p.E1499D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV101527456; called by muse, mutect2, varscan2
- MINAR1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100548837; called by muse, mutect2
- MKI67 | c.6665G>T p.R2222I | Missense Mutation (SNP) | VAF 48/314 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100896428, COSV64074982; called by muse, mutect2, varscan2
- MORC4 | c.1454+1G>C p.X485_splice | Splice Site (SNP) | VAF 10/141 reads (7%) | catalogued as COSV99717084; called by muse, mutect2
- MOSPD1 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100887829; called by muse, mutect2, varscan2
- MRC1 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 62/292 reads (21%) | catalogued as COSV100509580; called by muse, mutect2, varscan2
- MROH2B | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV101270636, COSV101270883; called by muse, mutect2
- MS4A12 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV50014311, COSV99188741; called by muse, mutect2, varscan2
- MUC16 | c.38978C>G p.T12993S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.646); catalogued as COSV101199512; called by muse, mutect2, varscan2
- MYH8 | c.2788G>C p.E930Q | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV67963004, COSV67964773; called by muse, mutect2, varscan2
- NAA25 | c.247C>G p.Q83E | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99927512; called by muse, mutect2, varscan2
- NCOA2 | c.3986G>T p.R1329L | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99144778; called by muse, mutect2, varscan2
- NEXMIF | c.2257C>A p.Q753K | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99280510; called by muse, mutect2, varscan2
- NFE2L3 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1044239343, COSV50242965, COSV99283645; called by muse, mutect2, varscan2
- NID2 | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs775445837, COSV99356355; called by muse, mutect2, varscan2
- NRBP1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99274959; called by muse, mutect2, varscan2
- NRG3 | c.2111C>T p.A704V (on ENST00000404547 / NM_001370084.1; = p.A680V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.666); catalogued as rs367831182; called by mutect2, varscan2
- OR10A7 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406551; called by muse, mutect2, varscan2
- OR2L13 | c.152A>G p.D51G | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813731; called by muse, mutect2
- OR2T3 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778713035; called by muse, mutect2, varscan2
- OR2T33 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs375842071, COSV58818740; called by muse, mutect2, varscan2
- OR2T8 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100178217; called by mutect2, varscan2
- OR2W1 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV101013906; called by muse, mutect2, varscan2
- OR52M1 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs765807772, COSV64172610; called by muse, mutect2, varscan2
- OR56A3 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100290175; called by muse, mutect2, varscan2
- OR6K2 | c.904A>T p.I302L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.033); catalogued as COSV100656769; called by muse, mutect2, varscan2
- OR8I2 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100135840; called by muse, mutect2, varscan2
- PCDH11X | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs779404695, COSV100011080; called by muse, mutect2, varscan2
- PCDHA13 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.08); catalogued as rs782231326, COSV99165842; called by muse, mutect2, varscan2
- PCDHAC2 | c.346C>G p.R116G | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.133); catalogued as COSV99145914; called by muse, mutect2, varscan2
- PCDHGA1 | c.2275C>A p.L759I | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100965983; called by muse, mutect2, varscan2
- PCLO | c.4417G>A p.E1473K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100431149; called by muse, mutect2, varscan2
- PCNT | c.1688G>A p.C563Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as rs367720344; called by muse, mutect2, varscan2
- PHEX | c.1104G>C p.W368C | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101039562; called by muse, mutect2, varscan2
- PIKFYVE | c.4994A>G p.K1665R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100010469; called by muse, mutect2, varscan2
- PKHD1L1 | c.5357A>T p.Q1786L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV101005989; called by muse, mutect2, varscan2
- PLCH1 | c.3143A>C p.H1048P (on ENST00000340059 / NM_001130960.2; = p.H1040P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.019); catalogued as COSV100396532; called by muse, mutect2, varscan2
- PMFBP1 | c.267A>T p.K89N | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99400690; called by muse, mutect2, varscan2
- POM121L12 | c.590G>T p.W197L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.93); catalogued as rs377144125; called by muse, mutect2, varscan2
- PPP1R15A | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as COSV99079364, COSV99565991; called by muse, mutect2, varscan2
- PPP4R4 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV100175668; called by muse, mutect2, varscan2
- PRKCG | c.1562A>G p.Y521C | Missense Mutation (SNP) | VAF 73/367 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202130595, COSV99668881; called by muse, mutect2, varscan2
- PRKD1 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.219); catalogued as COSV100119987, COSV59568189; called by muse, mutect2, varscan2
- PRUNE2 | c.1534T>C p.S512P | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100944474; called by muse, mutect2, varscan2
- PSME4 | c.4238T>A p.L1413Q | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101122454; called by muse, mutect2, varscan2
- PTCHD4 | c.307T>A p.S103T | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV100260599; called by muse, mutect2, varscan2
- RABGGTA | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV99252945; called by muse, mutect2, varscan2
- RBM4 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV100029598; called by muse, mutect2, varscan2
- RBP4 | c.13T>C p.W5R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1213587529, COSV101012259; called by muse, mutect2, varscan2
- REG3G | c.422T>A p.L141* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV99709388; called by muse, mutect2, varscan2
- RFPL2 | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as COSV50716765, COSV99964177; called by muse, mutect2, varscan2
- RGL3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100710504, COSV62699161; called by muse, mutect2, varscan2
- RNF41 | c.917T>G p.L306R | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100560194; called by muse, mutect2, varscan2
- RPGRIP1 | c.658A>T p.M220L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99250904; called by muse, mutect2, varscan2
- RRAGB | c.1054C>A p.R352S (on ENST00000262850 / NM_016656.4; = p.R324S on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV99469261; called by muse, varscan2
- RUNX3 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV100136821; called by muse, mutect2, varscan2
- SCN7A | c.2906A>C p.E969A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV101313176; called by muse, mutect2, varscan2
- SCN7A | c.1453T>A p.W485R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101313177; called by muse, mutect2, varscan2
- SH2D1A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100758295; called by muse, mutect2, varscan2
- SHROOM4 | c.2203C>G p.Q735E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV56792105, COSV99173305; called by muse, mutect2, varscan2
- SLC6A13 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100569882; called by muse, mutect2, varscan2
- SLC9A4 | c.1747A>G p.R583G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99762938; called by muse, mutect2, varscan2
- SMPD3 | c.1750T>A p.F584I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.304); catalogued as COSV99545571; called by muse, mutect2, varscan2
- SNRPN | c.295G>T p.G99* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV57594685; called by muse, mutect2, varscan2
- SNRPN | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100578132; called by muse, mutect2, varscan2
- SNX12 | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99339883; called by muse, mutect2
- SORCS1 | c.2492C>G p.T831R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99545505; called by muse, mutect2, varscan2
- SOX1 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV100446889, COSV58378326, COSV99044097; called by muse, mutect2, varscan2
- SPATA19 | c.126G>T p.W42C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100141084; called by muse, mutect2, varscan2
- SRPK3 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99473109; called by muse, mutect2, varscan2
- SRPK3 | c.1148-2A>T p.X383_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99473110; called by muse, mutect2, varscan2
- STARD8 | c.2480T>C p.L827P | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99366681; called by muse, mutect2, varscan2
- SUCLG2 | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV100214168; called by muse, mutect2, varscan2
- SYNE1 | c.12794G>C p.R4265T (on ENST00000367255 / NM_182961.4; = p.R4194T on NM_033071.3) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99561223; called by muse, mutect2, varscan2
- SYNJ1 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100449223; called by muse, mutect2, varscan2
- TACC1 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV99393412; called by muse, mutect2, varscan2
- TAF1 | c.3271A>G p.K1091E (on ENST00000373790 / NM_138923.4; = p.K1112E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99335489; called by muse, mutect2, varscan2
- TCAIM | c.1201A>G p.I401V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV100703243; called by muse, mutect2, varscan2
- TECTB | c.382T>A p.L128M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101027683; called by muse, mutect2, varscan2
- TENM1 | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV100949771; called by muse, mutect2, varscan2
- TEX13B | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV100258354; called by muse, mutect2
- THSD7A | c.2183G>T p.C728F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101448664; called by muse, mutect2, varscan2
- TLL1 | c.515-2A>G p.X172_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99286946; called by muse, mutect2, varscan2
- TOX2 | c.1386G>T p.W462C (on ENST00000358131 / NM_001098798.2; = p.W438C on NM_032883.3) | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100363746; called by muse, mutect2, varscan2
- TRIP10 | c.1199G>A p.R400Q (on ENST00000313244 / NM_001288962.2; = p.R344Q on NM_004240.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1283319243, COSV100505065; called by muse, mutect2, varscan2
- TTN | c.82116C>A p.F27372L (on ENST00000591111; = p.F19948L on NM_003319.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | PolyPhen probably damaging (0.984); catalogued as COSV100607385, COSV59906328; called by muse, mutect2
- TTN | c.74302C>A p.R24768S (on ENST00000591111; = p.R17344S on NM_003319.4) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | PolyPhen possibly damaging (0.511); catalogued as COSV100607392, COSV100623553; called by muse, mutect2, varscan2
- TTN | c.42055C>A p.P14019T (on ENST00000591111; = p.P6595T on NM_003319.4) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | PolyPhen probably damaging (0.964); catalogued as COSV100607397; called by muse, mutect2, varscan2
- TTN | c.22095G>T p.E7365D (on ENST00000591111; = p.E6438D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | PolyPhen probably damaging (0.97); catalogued as COSV100607400; called by muse, mutect2
- UHRF1BP1L | c.3215dup p.V1073Sfs*2 | Frame Shift Ins (INS) | VAF 20/98 reads (20%) | catalogued as rs750418659; called by mutect2, varscan2
- UNC13C | c.5893G>T p.E1965* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99515571; called by muse, mutect2, varscan2
- USP28 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV99135079; called by muse, mutect2, varscan2
- USP51 | c.1926T>A p.C642* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101540657; called by muse, mutect2
- USP9X | c.3143C>G p.P1048R | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100198985, COSV100199409; called by muse, mutect2, varscan2
- UTRN | c.9914C>G p.P3305R | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100838434; called by muse, mutect2, varscan2
- UXT | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV100243825; called by muse, mutect2, varscan2
- VIT | c.373T>G p.S125A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.765); catalogued as COSV101007353; called by muse, mutect2, varscan2
- VPS13C | c.6597A>C p.E2199D (on ENST00000644861 / NM_020821.3; = p.E2156D on NM_017684.5) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as COSV99828210; called by muse, mutect2
- WNT5A | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.309); catalogued as rs750646727, COSV99224840; called by muse, mutect2, varscan2
- XDH | c.1512G>T p.M504I | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101052175; called by muse, mutect2, varscan2
- ZBTB33 | c.1882G>C p.G628R | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.435); catalogued as rs1194422478, COSV100434140, COSV100434151; called by muse, mutect2, varscan2
- ZCCHC12 | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.503); catalogued as rs1249241749, COSV100038482; called by muse, mutect2, varscan2
- ZEB2 | c.2389C>A p.H797N | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV57953410; called by muse, mutect2, varscan2
- ZFP69B | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848244; called by muse, mutect2, varscan2
- ZNF157 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100998486; called by muse, mutect2, varscan2
- ZNF280A | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100131023; called by muse, mutect2, varscan2
- ZNF528 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100846611; called by muse, varscan2
- ZNF615 | c.1840C>A p.H614N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100943767; called by muse, mutect2, varscan2
- ZNF99 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as COSV101233807, COSV68055647; called by muse, mutect2
- ZSWIM2 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99720113; called by muse, mutect2, varscan2
- ZSWIM2 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV99720115; called by muse, mutect2, varscan2
- ZZZ3 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV100890282; called by muse, mutect2
- FARP2 | c.1022dup p.R342Qfs*25 | Frame Shift Ins (INS) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- LYZL6 | c.366del p.M123* | Frame Shift Del (DEL) | VAF 28/160 reads (18%) | called by mutect2, pindel, varscan2
- MGAM | c.2986dup p.C996Lfs*12 | Frame Shift Ins (INS) | VAF 23/143 reads (16%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.2477del p.P826Lfs*6 | Frame Shift Del (DEL) | VAF 36/226 reads (16%) | called by mutect2, pindel, varscan2
- NLRP8 | c.2611del p.H871Tfs*2 | Frame Shift Del (DEL) | VAF 31/188 reads (16%) | called by mutect2, pindel, varscan2
- STRADA | c.172del p.V58Sfs*2 (on ENST00000336174 / NM_001363786.1; = p.V21Sfs*2 on NM_153335.6) | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.717); called by mutect2, varscan2
- UBE2NL | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.181); called by muse, mutect2
- ADAMTS15 | c.189C>T p.D63= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100143306; called by muse, mutect2, varscan2
- ADAMTS19 | c.1734T>C p.L578= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV50744544, COSV99179350; called by muse, mutect2, varscan2
- ADGRG4 | c.8571T>A p.G2857= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99795243; called by muse, mutect2, varscan2
- ALPK1 | c.3105G>T p.G1035= | Silent (SNP) | VAF 44/180 reads (24%) | catalogued as COSV99453871; called by muse, mutect2, varscan2
- ANK1 | c.3183G>A p.L1061= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs1364544683, COSV99224881; called by muse, mutect2, varscan2
- AQP6 | c.264C>T p.A88= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV100210150; called by muse, mutect2, varscan2
- ARHGEF18 | c.453G>T p.L151= (on ENST00000359920 / NM_001130955.2; = p.L47= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as COSV100149413; called by muse, mutect2, varscan2
- CDH19 | c.1530T>A p.S510= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100051386; called by muse, mutect2, varscan2
- CDH19 | c.1302T>A p.A434= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100051387; called by muse, mutect2, varscan2
- CDR1 | c.102G>A p.L34= | Silent (SNP) | VAF 34/252 reads (13%) | called by muse, mutect2, varscan2
- CDX4 | c.252C>T p.S84= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs146093321, COSV65171604; called by muse, mutect2, varscan2
- CFL1 | c.318C>A p.P106= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs776644270, COSV100354034; called by muse, mutect2, varscan2
- CT83 | c.190C>A p.R64= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV100902566; called by muse, mutect2
- DACT1 | c.855T>C p.L285= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs760365379, COSV100241792; called by muse, mutect2, varscan2
- DDIAS | c.2385T>A p.P795= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100231159; called by muse, mutect2
- DPPA2 | c.63G>A p.E21= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV101524755; called by muse, varscan2
- EFEMP2 | c.1212G>T p.P404= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV100337235; called by muse, mutect2, varscan2
- EHMT1 | c.513G>A p.T171= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs765164018, COSV100603673; called by muse, mutect2, varscan2
- EPHA3 | c.2325A>T p.P775= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100344621; called by muse, mutect2, varscan2
- FDCSP | c.21G>A p.L7= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV58764756; called by muse, mutect2, varscan2
- FHL1 | c.60G>C p.V20= | Silent (SNP) | VAF 40/266 reads (15%) | catalogued as COSV100600757; called by muse, mutect2, varscan2
- GIGYF1 | c.1788G>C p.P596= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV51939392, COSV99309217; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.636A>C p.S212= (on ENST00000354667 / NM_031243.3; = p.S200= on NM_002137.4) | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV100522920; called by muse, mutect2, varscan2
- HRNR | c.2637C>A p.G879= | Silent (SNP) | VAF 47/138 reads (34%) | catalogued as rs747704480, COSV100913366, COSV64263948; called by muse, mutect2, varscan2
- ITSN2 | c.2427A>T p.P809= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100743240; called by muse, mutect2, varscan2
- KCNA3 | c.393C>A p.G131= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV100871177, COSV100871242; called by muse, mutect2
- KHDRBS2 | c.744G>T p.R248= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99832963; called by muse, mutect2, varscan2
- LIFR | c.2388G>A p.L796= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99664012; called by muse, mutect2, varscan2
- LONRF1 | c.2061T>A p.V687= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV101238201; called by muse, mutect2, varscan2
- LPAR5 | c.699G>A p.V233= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100320987; called by muse, mutect2, varscan2
- LRRIQ3 | c.1527C>A p.S509= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV100598683, COSV63043353; called by muse, mutect2
- MKI67 | c.3234A>T p.P1078= | Silent (SNP) | VAF 28/231 reads (12%) | catalogued as COSV100896429; called by muse, mutect2, varscan2
- MYO16 | c.3024G>A p.L1008= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100696576; called by muse, mutect2, varscan2
- NKX6-1 | c.924G>C p.S308= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs1298897545, COSV55684400, COSV99880023; called by muse, mutect2, varscan2
- NMNAT2 | c.12C>G p.T4= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV55078028, COSV99818001; called by muse, mutect2, varscan2
- NR0B1 | c.18C>T p.H6= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100973509; called by muse, mutect2, varscan2
- OR4C6 | c.195C>A p.S65= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV100051590, COSV100051854; called by muse, mutect2, varscan2
- OR5L2 | c.861C>A p.P287= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV101004301; called by muse, mutect2, varscan2
- OTOF | c.4839C>T p.S1613= (on ENST00000272371 / NM_194248.3; = p.S846= on NM_004802.4) | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99717364; called by muse, mutect2, varscan2
- PAX4 | c.687G>A p.E229= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV58388290; called by muse, mutect2, varscan2
- PCDHGA2 | c.1803C>T p.N601= | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as COSV54043364; called by muse, mutect2, varscan2
- PHKA2 | c.2925C>A p.S975= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV101176972; called by muse, mutect2, varscan2
- PKD1L2 | c.1014C>T p.T338= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as rs747070699, COSV100449812; called by muse, mutect2, varscan2
- PLA2G2E | c.428G>A p.*143= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs754756791, COSV100908809; called by muse, mutect2, varscan2
- PLEKHA7 | c.1170G>A p.R390= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV63052203; called by muse, mutect2, varscan2
- PMPCB | c.1170A>T p.T390= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99971219; called by muse, mutect2, varscan2
- PRB2 | c.489C>A p.P163= | Silent (SNP) | VAF 88/878 reads (10%) | catalogued as COSV101231404; called by muse, varscan2
- PSG7 | c.129A>G p.P43= | Silent (SNP) | VAF 28/211 reads (13%) | catalogued as rs782642468, COSV101343228, COSV68444422; called by muse, mutect2, varscan2
- PTPRM | c.688C>T p.L230= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs775915435, COSV100156715; called by muse, mutect2, varscan2
- RAPGEF1 | c.963G>A p.R321= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100940458; called by muse, mutect2, varscan2
- RPIA | c.258C>T p.G86= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1384729567, COSV99376084; called by muse, mutect2, varscan2
- RTL9 | c.1299C>G p.A433= | Silent (SNP) | VAF 35/270 reads (13%) | catalogued as COSV101511670, COSV71825440; called by muse, mutect2, varscan2
- SIRT2 | c.6A>G p.A2= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99979349; called by muse, mutect2, varscan2
- SLC43A3 | c.1416C>T p.H472= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs758127348, COSV100725180; called by muse, mutect2, varscan2
- SLC5A1 | c.594G>A p.A198= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as rs184213779, COSV56688485, COSV99833335; called by muse, mutect2, varscan2
- SPTA1 | c.6867G>C p.G2289= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100934767; called by muse, mutect2, varscan2
- STAG2 | c.787A>C p.R263= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99493130; called by muse, mutect2, varscan2
- SYNE1 | c.11115G>A p.Q3705= (on ENST00000367255 / NM_182961.4; = p.Q3690= on NM_033071.3) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV54899977, COSV99572956; called by muse, mutect2, varscan2
- SYT16 | c.1293T>C p.C431= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101413567; called by muse, mutect2, varscan2
- TBC1D25 | c.936G>A p.R312= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100952136; called by muse, mutect2, varscan2
- UGGT1 | c.3858G>C p.V1286= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99390584; called by muse, mutect2, varscan2
- UNC93A | c.126G>T p.A42= | Silent (SNP) | VAF 104/222 reads (47%) | catalogued as rs202134214, COSV100023263, COSV57810533; called by muse, mutect2, varscan2
- UPRT | c.153C>A p.L51= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100974480; called by muse, mutect2, varscan2
- XRN2 | c.2340A>T p.V780= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV101018244; called by muse, mutect2, varscan2
- ZEB2 | c.2388C>A p.S796= | Silent (SNP) | VAF 20/169 reads (12%) | catalogued as COSV100355769; called by muse, mutect2, varscan2
- ZNF114 | c.123C>T p.N41= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV100252014; called by muse, mutect2
- ZNF182 | c.1419C>G p.L473= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100527008; called by muse, mutect2, varscan2
- AC005863.1 | n.163G>A | RNA (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- DCHS2 | n.2565C>T | RNA (SNP) | VAF 22/66 reads (33%) | catalogued as rs747837457, COSV100251602; called by muse, mutect2, varscan2
- DELEC1 | n.592G>T | RNA (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100927027; called by muse, mutect2, varscan2
- HERC2P3 | n.447C>A | RNA (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- MAGEA5 | n.80G>T | RNA (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- MAGEA5 | n.79G>T | RNA (SNP) | VAF 20/135 reads (15%) | called by muse, mutect2, varscan2
- MIR1251 | n.44_46delinsAA | RNA (DEL) | VAF 22/94 reads (23%) | called by pindel, varscan2*
- NUDCD3 | c.509+17066G>A | Intron (SNP) | VAF 22/126 reads (17%) | catalogued as rs1275479698; called by muse, mutect2, varscan2
- SNORD116-5 | n.91G>A | RNA (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
